Somatic mutation profile of tumor specimen 0DLBMK from CCDI case PBBZAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,790 days).
Specimen 0DLBMK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 083cbaa1-507c-45b5-90b3-605cde586f35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBLX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9999513-7e55-4fa5-8ae9-8eadc792c832

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP85 | c.1095-3C>T | Splice Region (SNP) | VAF 46/262 reads (18%) | catalogued as rs778646112; called by muse, mutect2, varscan2
- COL4A6 | c.1961C>A p.T654N | Missense Mutation (SNP) | VAF 24/553 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2
- REV3L | c.6545T>A p.I2182K | Missense Mutation (SNP) | VAF 53/1272 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- DENND1B | c.1350+70T>C | Intron (SNP) | VAF 22/463 reads (5%) | catalogued as rs1484940653; called by muse, mutect2
- ENTR1 | c.-83_-82insGGGGGGGGCGACG | 5'UTR (INS) | VAF 17/45 reads (38%) | called by mutect2, varscan2*
